Gene-level copy-number profile of tumor specimen TCGA-A6-5656-01A from TCGA case TCGA-A6-5656, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.4 years (27,184 days).
Specimen TCGA-A6-5656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.fd7e8f54-6065-4d9a-a5b6-f8c97849085b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5656-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cac8cb11-b0f3-4219-b786-6decea89f6cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,873; copy number 2: 42,901; copy number 3: 4,386; copy number 4: 2,229; copy number 5: 1,462; copy number 6: 956; copy number 11: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5656-01A-21D-A274-01): tumor purity 0.8, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,430 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,030,534–38,213,301, 12 genes, copy number 11 (within-gene range 2–11): EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4.
- chr8:51,810,110–53,484,067, 23 genes, copy number 5 (within-gene range 3–5): AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2.
- chr8:55,067,585–84,142,463, 431 genes, copy number 5 (broad region; genes not listed).
- chr8:86,866,415–113,950,998, 400 genes, copy number 5 (broad region; genes not listed).
- chr8:116,950,273–145,066,685, 495 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:82,778,208–83,102,335, 2 genes, copy number 5: AL445255.1, GYG1P2.
- chr20:2,780,614–6,528,459, 110 genes, copy number 5–6 (broad region; genes not listed).
- chr20:7,255,053–11,926,609, 61 genes, copy number 5 (broad region; genes not listed).
- chr20:30,294,550–64,313,132, 896 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,873. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
